Somatic mutation profile of tumor specimen TCGA-FS-A1YY-06A (aliquot TCGA-FS-A1YY-06A-11D-A197-08) from TCGA case TCGA-FS-A1YY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.0 years (27,014 days).
Specimen TCGA-FS-A1YY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95fef36e-5cff-4a8e-bfe0-fdc4258953ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1YY-10A (Blood Derived Normal), aliquot TCGA-FS-A1YY-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20dc1c3e-6474-4a27-96be-026caae4ff7d

The open-access MAF lists 246 somatic variants for this specimen: 159 protein-altering or splice-affecting, 84 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 84, Nonsense Mutation 9, Splice Region 4, In Frame Del 3, Frame Shift Del 1, Splice Site 1, Intron 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC12 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV60911972; called by muse, mutect2, varscan2
- ABCF1 | c.1382C>T p.S461F (on ENST00000326195 / NM_001025091.2; = p.S423F on NM_001090.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58230812; called by muse, mutect2, varscan2
- ABL1 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59341558; called by muse, mutect2, varscan2
- ADAMTS16 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763036633, COSV57007658, COSV99943421; called by muse, mutect2, varscan2
- ADAMTS20 | c.1994A>G p.Y665C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs535734189, COSV67139767; called by muse, mutect2, varscan2
- ADH1C | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV72463670; called by muse, mutect2, varscan2
- ALOXE3 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as rs768352670, COSV59078051; called by muse, mutect2, varscan2
- AMPD1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV62416345; called by muse, mutect2, varscan2
- ANKRD13C | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99256020; called by muse, mutect2, varscan2
- AOAH | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs777448004, COSV51750909; called by muse, mutect2, varscan2
- ARGFX | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1196486208, COSV57681687; called by muse, mutect2, varscan2
- ASTL | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs747687030, COSV60904288; called by muse, mutect2, varscan2
- C8orf34 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV61397643; called by muse, mutect2, varscan2
- CA10 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53373561; called by muse, mutect2, varscan2
- CALCA | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs781962903, COSV100523853, COSV59028793; called by muse, mutect2, varscan2
- CCDC102B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV60144441; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CD22 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1303959389, COSV50069990; called by muse, mutect2, varscan2
- CD5L | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV63823171; called by muse, mutect2, varscan2
- CDCA7L | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62261666; called by muse, mutect2, varscan2
- CHM | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63304736; called by muse, mutect2, varscan2
- CHST10 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV51807732; called by muse, mutect2, varscan2
- COL15A1 | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as COSV66649392; called by muse, varscan2
- COL1A1 | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56809673; called by muse, mutect2, varscan2
- CRISP3 | c.288G>A p.W96* (on ENST00000371159 / NM_001368123.1; = p.W78* on NM_006061.4) | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV53820043; called by muse, mutect2, varscan2
- CSMD2 | c.9014C>T p.P3005L | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53965280; called by muse, mutect2, varscan2
- CTNND2 | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV58929577; called by muse, mutect2, varscan2
- DACT1 | c.2204A>G p.H735R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60023583; called by muse, mutect2, varscan2
- DLX5 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56034421; called by muse, mutect2, varscan2
- DMD | c.4143A>T p.L1381F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV63793134; called by muse, mutect2, varscan2
- DNAH10 | c.12452G>A p.G4151E (on ENST00000409039; = p.G4090E on NM_207437.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69002296; called by muse, mutect2, varscan2
- DNAH5 | c.7642G>A p.E2548K | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV54227825; called by muse, mutect2, varscan2
- DNAH5 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as COSV54208238; called by muse, mutect2, varscan2
- DSG2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55203111, COSV99853436; called by muse, mutect2, varscan2
- DUOX2 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101199507, COSV66534774; called by muse, mutect2, varscan2
- ELOA2 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs774453041, COSV55301700; called by muse, mutect2, varscan2
- EPGN | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV59741059; called by muse, mutect2, varscan2
- FARP1 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.526); catalogued as COSV100129294; called by muse, mutect2, varscan2
- FARP1 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV100129297, COSV60339632; called by muse, mutect2, varscan2
- FBLN5 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752012733, COSV50909870; called by muse, mutect2, varscan2
- FBN3 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.103); catalogued as COSV54473524; called by muse, mutect2, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, mutect2, varscan2
- FREM1 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66525361, COSV66527815; called by muse, mutect2, varscan2
- FSTL5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60231550; called by muse, mutect2, varscan2
- FUT9 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.593); catalogued as COSV56157390; called by muse, mutect2, varscan2
- GABRQ | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.864); catalogued as COSV64783992; called by muse, mutect2, varscan2
- GFRAL | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61235603; called by muse, mutect2, varscan2
- GK2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776385662, COSV62625914, COSV62628380; called by muse, mutect2, varscan2
- GPR20 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.206); catalogued as COSV66685094; called by muse, mutect2, varscan2
- GPR50 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 38/153 reads (25%) | catalogued as COSV54437973, COSV54439238; called by muse, mutect2, varscan2
- GRIK3 | c.1720C>A p.L574M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100901767, COSV66147215; called by muse, mutect2, varscan2
- GRIN2A | c.2528G>A p.W843* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as rs1555483669, COSV58053088; called by muse, mutect2, varscan2
- GRIN2A | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV58030024, COSV58033035; called by muse, varscan2
- GZF1 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs902374939, COSV57638450; called by muse, mutect2, varscan2
- H2BC1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV51238482; called by muse, mutect2, varscan2
- HEPH | c.2812G>A p.E938K (on ENST00000343002; = p.E671K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV57958731; called by muse, mutect2, varscan2
- HERC2 | c.798G>A p.T266= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs750115906, COSV55311363, COSV99871530; called by muse, mutect2, varscan2
- HIP1 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV61191644; called by muse, mutect2, varscan2
- IL15RA | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66093225; called by muse, mutect2, varscan2
- IPO5 | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs761838822, COSV55160091; called by muse, mutect2, varscan2
- IST1 | c.190C>T p.R64* (on ENST00000535424 / NM_001270976.1; = p.R51* on NM_014761.4) | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs776680375, COSV61711190; called by muse, mutect2, varscan2
- KIAA1109 | c.11155G>C p.D3719H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV52693041; called by muse, mutect2, varscan2
- KMT2D | c.10909C>T p.P3637S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV99976558; called by muse, mutect2, varscan2
- LIFR | c.2660G>A p.S887N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54700501; called by muse, mutect2, varscan2
- LRRC25 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV53251785; called by muse, mutect2, varscan2
- MAGED1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV58516945; called by muse, mutect2
- MAP3K1 | c.3088C>T p.H1030Y | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV68127574; called by muse, mutect2, varscan2
- MECP2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 113/310 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs786205894, COSV57657270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED24 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV62421000; called by muse, mutect2, varscan2
- MINPP1 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV64355559; called by muse, mutect2, varscan2
- MROH2B | c.4341G>T p.K1447N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs200154112; called by muse, mutect2, varscan2
- MT4 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV54642331, COSV54643089; called by muse, mutect2, varscan2
- MTNR1B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as rs754089451, COSV57069050; called by muse, mutect2, varscan2
- MUC16 | c.33578C>T p.S11193L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as COSV67495392; called by muse, mutect2, varscan2
- MUC16 | c.16772G>A p.G5591E | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.005); catalogued as COSV67476342, COSV67495398; called by muse, mutect2, varscan2
- MUC4 | c.13807G>A p.G4603S (on ENST00000463781 / NM_018406.7; = p.G367S on NM_004532.6) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as COSV57803788; called by muse, mutect2, varscan2
- NCAN | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV53059374; called by muse, mutect2, varscan2
- NFASC | c.3673G>A p.E1225K (on ENST00000339876 / NM_001378329.1; = p.E1154K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1249999680, COSV58380859; called by muse, mutect2, varscan2
- NKAIN2 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV63732103; called by muse, mutect2, varscan2
- NLRP13 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs567099653, COSV61622778; called by muse, mutect2, varscan2
- NLRP13 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV61623218, COSV61624142; called by muse, mutect2, varscan2
- NLRP4 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 88/136 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV56723645; called by muse, mutect2, varscan2
- NRK | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54607249; called by muse, mutect2, varscan2
- NWD1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as COSV100342430, COSV60352058; called by muse, mutect2, varscan2
- OR4C15 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs769319726, COSV58955625; called by muse, mutect2, varscan2
- OR52N4 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs775871765, COSV57893172; called by muse, mutect2, varscan2
- OR9A4 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV101516569, COSV71885963, COSV71886114; called by muse, mutect2, varscan2
- OTOGL | c.4988G>A p.G1663E (on ENST00000547103; = p.G1654E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54024152; called by muse, mutect2, varscan2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PAPPA2 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.241); catalogued as COSV62812103; called by muse, mutect2, varscan2
- PCDHGA3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV53895418, COSV53988497; called by muse, mutect2, varscan2
- PCDHGC4 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs766519569, COSV99337128; called by muse, mutect2, varscan2
- PCSK1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs768268374, COSV60737654; called by muse, mutect2, varscan2
- PDP1 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745958515, COSV52602616; called by muse, mutect2, varscan2
- PHACTR2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs772630354, COSV59859572; called by muse, mutect2, varscan2
- PIK3CB | c.2377A>G p.K793E | Missense Mutation (SNP) | VAF 188/583 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56690480; called by muse, mutect2, varscan2
- PLCB3 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54188685; called by muse, mutect2, varscan2
- PLEKHA7 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.977); catalogued as rs1279744626, COSV63051268; called by muse, mutect2, varscan2
- PLXDC2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.289); catalogued as rs540394643, COSV65909263; called by muse, mutect2, varscan2
- PLXNA4 | c.3808A>C p.T1270P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58161442; called by muse, mutect2, varscan2
- PRDM9 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV57013247; called by muse, mutect2, varscan2
- RAD21 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV52059266; called by muse, mutect2, varscan2
- RAF1 | c.860C>A p.S287* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV52584310; called by muse, mutect2, varscan2
- RBMXL2 | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV60981740; called by muse, mutect2, varscan2
- RFX6 | c.2512C>T p.H838Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV60587739; called by muse, mutect2, varscan2
- RGS7 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58544846; called by muse, mutect2, varscan2
- RMDN2 | c.1044G>A p.K348= (on ENST00000354545 / NM_001322212.2; = p.K526= on NM_144713.5) | Splice Region (SNP) | VAF 21/33 reads (64%) | catalogued as COSV52229850; called by muse, mutect2, varscan2
- RNF17 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55046867; called by muse, mutect2, varscan2
- RPS6KA1 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.949); catalogued as COSV65176538; called by muse, mutect2, varscan2
- RPSA | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100087984; called by muse, mutect2, varscan2
- SDK1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV67379006, COSV67389160; called by muse, varscan2
- SDK1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs868364296, COSV67368939; called by muse, mutect2, varscan2
- SERPINA7 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV59666552, COSV59667010; called by muse, mutect2, varscan2
- SHANK1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53262791; called by muse, varscan2
- SLC25A31 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs779889234, COSV55418886; called by muse, mutect2, varscan2
- SLCO6A1 | c.2023C>T p.L675F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs768590757, COSV65814924; called by muse, mutect2, varscan2
- SPTBN4 | c.2879C>T p.S960F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV58959144; called by muse, mutect2, varscan2
- STRN | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55748053; called by muse, mutect2, varscan2
- STX1B | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV53062239, COSV99288097; called by muse, mutect2, varscan2
- SUPT3H | c.899C>T p.A300V (on ENST00000371460 / NM_181356.3; = p.A289V on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as COSV60951919; called by mutect2, varscan2
- SYNM | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV60373601; called by muse, varscan2
- TBC1D21 | c.894G>A p.L298= | Splice Region (SNP) | VAF 24/73 reads (33%) | catalogued as rs1227329376, COSV55996866; called by muse, mutect2, varscan2
- TBCEL | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); catalogued as rs267602731, COSV52458519, COSV52459005; called by muse, mutect2, varscan2
- TCEA2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV58659478; called by muse, mutect2
- TCEA2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100180932, COSV58659491; called by muse, mutect2
- TCEA3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs774600357, COSV65841383; called by muse, mutect2, varscan2
- TEX101 | c.559G>A p.A187T (on ENST00000598265 / NM_001130011.3; = p.A205T on NM_031451.4) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as COSV53663217; called by muse, varscan2
- TFEC | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV55407386; called by muse, mutect2, varscan2
- TK2 | c.115C>T p.L39= (on ENST00000299697; = p.L95= on NM_004614.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 41/123 reads (33%) | catalogued as COSV55284216; called by muse, mutect2, varscan2
- TLN2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750791867, COSV60887439; called by muse, mutect2, varscan2
- TLR9 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59727633; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56696459; called by muse, mutect2, varscan2
- TMEM200A | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV51659861; called by muse, mutect2, varscan2
- TMPRSS11F | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.723); catalogued as rs1261174212, COSV62469640; called by muse, mutect2, varscan2
- TNXB | c.5767C>T p.R1923C (on ENST00000647633; = p.R1676C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766097197, COSV64489154; called by muse, mutect2, varscan2
- TOGARAM2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as rs752814009, COSV65424013; called by muse, mutect2, varscan2
- TRIM9 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53617544; called by muse, mutect2, varscan2
- TRMT10A | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV56746143; called by muse, mutect2, varscan2
- TSHZ2 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867002096, COSV61591701; called by muse, mutect2, varscan2
- TTC21B | c.3148C>T p.R1050W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218490524, COSV54627904; called by muse, varscan2
- UGT2B10 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV55321546, COSV55321992, COSV55323739; called by muse, mutect2, varscan2
- VPS41 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.072); catalogued as COSV59653406; called by muse, mutect2, varscan2
- WDR64 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63800757; called by muse, mutect2, varscan2
- XPOT | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV60348458; called by muse, mutect2
- ZFPM2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV65875978, COSV99059178; called by muse, mutect2
- ZNF423 | c.3244C>T p.R1082C (on ENST00000563137 / NM_001379286.1; = p.R1074C on NM_015069.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs373906393; called by muse, mutect2, varscan2
- ZNF676 | c.730C>T p.L244F (on ENST00000650058; = p.L212F on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV68093309; called by muse, mutect2, varscan2
- ZNF681 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1037392108, COSV68073537; called by muse, mutect2, varscan2
- ZNF75D | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV66133514; called by muse, mutect2, varscan2
- B4GALT1 | c.185_205del p.G62_A68del | In Frame Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CT45A1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 92/1062 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHA2 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCGF2 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PTPN23 | c.4860_4862del p.D1622del | In Frame Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- REG1A | c.482_485del p.V161Afs*14 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- SPATA31A3 | c.2130_2156del p.S711_R719del | In Frame Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel
- ACE | c.2397C>T p.L799= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV52013354; called by muse, mutect2, varscan2
- ACTL9 | c.594G>A p.T198= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1253093364, COSV61005366; called by muse, mutect2, varscan2
- ADGRA1 | c.99G>A p.L33= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV66931859; called by muse, mutect2, varscan2
- AKR1B1 | c.225C>T p.I75= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs115549384, COSV53648899; called by muse, mutect2, varscan2
- ALDH3A1 | c.90G>A p.L30= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1205763566, COSV99855695; called by muse, mutect2, varscan2
- ALPK2 | c.1779G>A p.R593= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV64497385; called by muse, mutect2, varscan2
- ALPP | c.664C>T p.L222= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV67398135; called by muse, mutect2, varscan2
- ANKRD13C | c.267C>T p.S89= | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as rs1298768012, COSV99256017; called by muse, mutect2, varscan2
- APC | c.3441C>T p.Y1147= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as CD972000, CM058099, CM106367, COSV57384006, COSV99965890; called by muse, mutect2, varscan2
- APOB | c.6780C>T p.I2260= | Silent (SNP) | VAF 247/406 reads (61%) | catalogued as COSV51953373, COSV99264866; called by muse, mutect2, varscan2
- ATP7B | c.243C>T p.S81= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV54444557; called by muse, mutect2, varscan2
- BMP3 | c.741C>T p.A247= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as rs1007409366, COSV51095745; called by muse, mutect2, varscan2
- BTRC | c.1776C>T p.P592= (on ENST00000370187 / NM_033637.4; = p.P556= on NM_003939.5) | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV64581063; called by muse, mutect2, varscan2
- C6 | c.1470C>T p.I490= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs760389028, COSV54705258, COSV54712571; called by muse, mutect2, varscan2
- CACNA1C | c.141G>A p.G47= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59774218; called by muse, varscan2
- CALML5 | c.207C>T p.F69= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV66702754; called by muse, mutect2, varscan2
- CDC42BPB | c.426C>T p.A142= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs761413152, COSV63476915; called by muse, mutect2, varscan2
- CDH20 | c.873C>T p.S291= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV53018437; called by muse, mutect2, varscan2
- CELSR3 | c.9753C>T p.A3251= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV51155387; called by muse, mutect2, varscan2
- CHSY1 | c.1380G>A p.G460= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54256159; called by muse, mutect2, varscan2
- CNR1 | c.69G>A p.V23= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV62991452; called by muse, mutect2, varscan2
- COL4A5 | c.4140C>T p.I1380= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100090744, COSV60372506; called by muse, mutect2
- CPNE4 | c.774G>A p.G258= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV70200309; called by muse, mutect2, varscan2
- CYP2F1 | c.222G>A p.R74= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as COSV58527247; called by muse, mutect2, varscan2
- DAPK2 | c.165G>A p.K55= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs763131157, COSV56046354; called by muse, mutect2, varscan2
- DHX16 | c.1917C>T p.I639= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV64565704; called by muse, mutect2, varscan2
- DNAH1 | c.4731T>C p.G1577= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV70236543; called by muse, mutect2, varscan2
- EHMT1 | c.1152G>A p.E384= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV58382114; called by muse, mutect2, varscan2
- ERC2 | c.1461C>T p.I487= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV55665472; called by muse, mutect2, varscan2
- FBN3 | c.2628C>T p.F876= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1249118451, COSV54473513; called by muse, mutect2, varscan2
- FIP1L1 | c.1080C>T p.F360= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV60994001; called by muse, mutect2, varscan2
- FOXN2 | c.1215C>T p.L405= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs748357224, COSV61319941; called by muse, mutect2, varscan2
- GAK | c.3492C>T p.V1164= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1243589309, COSV58509929; called by muse, mutect2, varscan2
- GCN1 | c.6288C>T p.F2096= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56104404; called by muse, mutect2
- GRM7 | c.1545C>T p.V515= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV63144025; called by muse, mutect2, varscan2
- HBD | c.135C>T p.S45= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV53083203; called by muse, mutect2, varscan2
- HTR5A | c.882C>T p.F294= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as rs145653373, COSV55285251; called by muse, mutect2, varscan2
- KATNAL1 | c.874T>C p.L292= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV66064919; called by muse, mutect2, varscan2
- KMT2D | c.10908C>T p.L3636= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56447516; called by muse, mutect2, varscan2
- KPRP | c.654C>T p.F218= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as rs1055172800, COSV64221260; called by muse, mutect2, varscan2
- KSR1 | c.1701G>A p.R567= (on ENST00000644974 / NM_001367810.1; = p.R452= on NM_014238.2) | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1411188369, COSV52039518; called by muse, mutect2, varscan2
- LRRC28 | c.450C>T p.P150= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs762852282, COSV57336626; called by muse, mutect2, varscan2
- LRRTM2 | c.1266G>A p.R422= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as rs770258740, COSV51225092; called by muse, mutect2, varscan2
- MAML3 | c.2187C>T p.F729= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1298209644, COSV72210279; called by muse, mutect2, varscan2
- MAP7D2 | c.1482A>G p.Q494= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV65530391; called by muse, mutect2
- MEFV | c.1059C>T p.P353= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs988793460, COSV54827868; called by muse, varscan2
- MMP11 | c.1410C>T p.P470= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs1468291060, COSV53156338; called by muse, mutect2, varscan2
- MUC16 | c.43005C>T p.S14335= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV66696781; called by muse, mutect2, varscan2
- MUC16 | c.37596C>T p.S12532= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV67466220; called by muse, mutect2, varscan2
- MYO19 | c.1968C>T p.F656= (on ENST00000614623 / NM_001163735.1; = p.F456= on NM_025109.5) | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- NAA25 | c.1611C>T p.I537= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV55709391; called by muse, mutect2, varscan2
- NFIC | c.1095G>A p.R365= | Silent (SNP) | VAF 90/372 reads (24%) | catalogued as COSV59416969; called by muse, mutect2, varscan2
- NME8 | c.951G>A p.K317= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV52247904, COSV99552619; called by muse, mutect2, varscan2
- NMRAL1 | c.858C>T p.D286= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as COSV52061215; called by muse, mutect2, varscan2
- OR2L13 | c.198C>T p.S66= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as COSV63550319; called by muse, mutect2, varscan2
- OR2M3 | c.876C>A p.L292= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV71759296; called by muse, mutect2, varscan2
- OR4A15 | c.891G>A p.R297= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV59034024; called by muse, mutect2, varscan2
- OR4A47 | c.454C>T p.L152= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV71444845; called by muse, mutect2, varscan2
- OR51E2 | c.96C>T p.S32= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs1234884522, COSV67808298; called by muse, mutect2, varscan2
- OR8D4 | c.471G>A p.V157= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as rs367878980; called by muse, mutect2, varscan2
- OSBPL7 | c.558C>T p.S186= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV50115863; called by muse, mutect2, varscan2
- PTPRB | c.3675G>A p.T1225= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs772280714, COSV54238505, COSV99717076; called by muse, mutect2, varscan2
- PTPRD | c.2655C>T p.I885= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100643370, COSV61982646; called by muse, mutect2, varscan2
- RRNAD1 | c.303C>T p.T101= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV57461348; called by muse, mutect2, varscan2
- SCNN1D | c.1600C>T p.L534= (on ENST00000338555; = p.L698= on NM_001130413.4) | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV57644564; called by muse, mutect2, varscan2
- SLFN5 | c.840C>T p.F280= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV55483629; called by muse, mutect2, varscan2
- SLX4IP | c.636C>T p.S212= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV57951570; called by muse, mutect2, varscan2
- SMARCA4 | c.4101C>T p.F1367= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs772075876, COSV60809771; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMPD3 | c.234G>A p.A78= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs147838351; called by muse, mutect2, varscan2
- SPACA1 | c.192G>A p.P64= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs754914513, COSV52761542; called by muse, mutect2, varscan2
- SPATA31A3 | c.2793C>T p.L931= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1188001589; called by mutect2, varscan2
- SRC | c.435C>T p.S145= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV62441254; called by muse, mutect2, varscan2
- STXBP3 | c.1158C>T p.S386= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs773581158, COSV64183629; called by muse, mutect2, varscan2
- TJP3 | c.1188G>A p.L396= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV53665824; called by muse, mutect2, varscan2
- TPH2 | c.1203C>T p.D401= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV61594448; called by muse, mutect2, varscan2
- TPRG1L | c.447G>A p.Q149= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs1282860117, COSV54563519; called by muse, mutect2, varscan2
- TTC21A | c.264C>T p.I88= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100073302, COSV57189621; called by muse, mutect2, varscan2
- TTN | c.23022G>A p.L7674= (on ENST00000591111; = p.L6747= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV60360627; called by muse, mutect2, varscan2
- UROC1 | c.645C>T p.P215= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV52039464; called by muse, mutect2, varscan2
- XIRP1 | c.4722C>T p.F1574= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as COSV61137850; called by muse, mutect2, varscan2
- ZMYM3 | c.1938C>T p.L646= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58740888; called by muse, mutect2, varscan2
- ZNF613 | c.240C>T p.I80= (on ENST00000293471 / NM_001031721.4; = p.I44= on NM_024840.4) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53274103; called by muse, mutect2
- ZNF646 | c.4698C>T p.F1566= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV54926736; called by muse, mutect2, varscan2
- ZNF74 | c.639C>T p.A213= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV62624321; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3853G>A | Intron (SNP) | VAF 7/11 reads (64%) | catalogued as COSV66931856; called by muse, varscan2
- AL353804.6 | chrX:73826425 G>A | 3'Flank (SNP) | VAF 12/35 reads (34%) | catalogued as rs756474649; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847235 C>T | 5'Flank (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
